Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3M2, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3M2-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

* Addendum *

Patient:

Physician:

CC:

Patient Address:

Date of Receipt:

Date of Report:

....

Clinical Diagnosis & History:
Left retroperitoneal mass.

Specimens Submitted:

- 1: Spleen
- 2: Left retroperitoneal sarcoma
- 3: Final diaphragm margin

DIAGNOSIS:

1. Spleen and omentum; resection:
- Spleen with no pathologic diagnosis
- Mature adipose tissue with rare atypical cells. The findings are not definitive for a diagnosis of well-differentiated liposarcoma
2. Retroperitoneum, Kidney, peri-nephric adipose tissue, mass, resection:
- Dedifferentiated Liposarcoma.
- The tumor measures 10 cm in greatest dimension.
- The dedifferentiated component predominates and shows low and high grade spindle cell sarcoma with focal myxoid change.
- Focal well-differentiated liposarcoma present.
- Well-differentiated liposarcoma component focally extends to the resection margin.
- Necrosis present. (15% of tumor)
- Tumor abuts the renal capsule without infiltrating it.
- Attached kidney and ureter are unremarkable.

Note: Immunohistochemical stains for CDK4 and MDM2 are being performed and will be reported in an addendum. Selected slides of the tumor were also reviewed by Dr. who agrees with the above diagnosis.

3. Final diaphragm margin; excision:
- Benign fibro-adipose tissue and skeletal muscle.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

** Continued on next page **

ICD-0-3

dedifferentiated liposarcoma 8858/3

Site: retroperitoneum C48.0

hw
12/23/11

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Accession #: [REDACTED]

Date of Report: [REDACTED]

----- Page 2 of 4

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh labeled "spleen, splenic hilar omentum" and consists of a spleen measuring 12 x 10 x 3.5 cm and weighing 193.5 gm. A fragment of adipose tissue measuring 25 x 10 x 2 cm is also present and shows no grossly obvious tumor implants. Numerous ill-defined slightly firmer congested areas are seen in the omentum and representatively submitted. Representative sections submitted.

Summary of sections:

S- spleen

O-omentum

2. The specimen is received fresh labeled "left retro-peritoneal sarcoma" and consists of a kidney measuring 12 x 7.5 x 4.5 cm with attached perinephric adipose tissue measuring 12 x 15 x 7 cm and attached ureter measuring 12 x 0.6 cm. A short stitch marks superior margin and a long stitch marks lateral margin, as per surgeon. The margins/surface of resection are inked as follow: superior: green, posterior: black, anterior: blue, inferior: yellow, lateral: orange, medial: red. A 10 x 8 x 8.5 cm mass is present the superior pole of the kidney, abutting the capsule but not grossly invading it. Cut section of the mass is 80% yellow-tan firm and 15% gelatinous. The mass appears encapsulated (thin capsule) and abuts the superior, posterior, medial and lateral margins and is away from the inferior margin. Kidney parenchyma is grossly normal. Representative sections submitted. TPS submitted. Photograph taken.

Summary of sections:

SPM: mass in relation to superior and posterior margins

LM: mass in relation to lateral margin

MM: mass in relation to medial margin

IM: inferior margin

UM: ureteral margin

TK: tumor in relation to kidney

T: tumor (slides 9-10 represent the gelatinous areas, slides 11 - 13 represent the firmer area)

NK: normal kidney

3) The specimen is received fresh, labeled "final diaphragm margin" and consists of an irregular pink-tan to gray purple portion of membranous soft tissue measuring 4.5 x 3.5 x 1.0 cm. The specimen is sectioned and representatively submitted.

Summary of sections:

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Accession #: [REDACTED]

Date of Report: [REDACTED]

----- Page 3 of 4
U - undesignated

Summary of Sections:

Part 1: Spleen

Block	Sect.	Site	PCs
5		o	5
2		s	2

Part 2: Left retroperitoneal sarcoma

Block	Sect.	Site	PCs
1		IM	1
1		LM	1
1		MM	1
1		NK	1
2		SPM	2
5		T	5
2		TK	2
1		UM	1

Part 3: Final diaphragm margin

Block	Sect.	Site	PCs
2		U	4

Procedures/Addenda:

Addendum

Date Ordered:

Status: Signed Out

Date Complete:

Date Reported:

Addendum Diagnosis

2. Retroperitoneum, Kidney, perinephric adipose tissue, mass, resection:

Immunohistochemical stains for CDK4 and MDM2 are negative.

*** Report Electronically Signed Out ***

Signed out by

** Continued on next page **

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Accession #: [REDACTED]

Date of Report: [REDACTED]

Page 4 of 4

** End of Report **

Source: NCI Genomic Data Commons file 1f7ed93c-5ee6-44bb-91b7-f66db58f2da6 (TCGA-DX-A3M2.A83970F1-3F0B-43F5-9E64-9BAEB8F9D2A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).